Somatic mutation profile of tumor specimen TCGA-55-6985-01A (aliquot TCGA-55-6985-01A-11D-1945-08) from TCGA case TCGA-55-6985, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 58.5 years (21,381 days).
Specimen TCGA-55-6985-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 455d4d85-b525-458c-ae66-61782f685527.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6985-11A (Solid Tissue Normal), aliquot TCGA-55-6985-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fd0843f-92c9-4e4f-b75e-d351758a2070

The open-access MAF lists 472 somatic variants for this specimen: 357 protein-altering or splice-affecting, 101 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 309, Silent 101, Nonsense Mutation 23, Splice Site 12, Frame Shift Del 8, Intron 7, Frame Shift Ins 5, RNA 2, 3'UTR 2, 3'Flank 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.938A>T p.Q313L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV55965551; called by muse, mutect2, varscan2
- AC008397.2 | c.382T>C p.Y128H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV53208167; called by muse, mutect2
- ACAD11 | c.1882C>A p.L628I | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53898432; called by muse, mutect2, varscan2
- ACSM2B | c.1282-1G>T p.X428_splice | Splice Site (SNP) | VAF 23/159 reads (14%) | catalogued as COSV61658665; called by muse, mutect2, varscan2
- ACSM5 | c.1030C>A p.L344M | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as COSV59372930; called by muse, mutect2, varscan2
- ACTB | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV59319508; called by muse, mutect2, varscan2
- ACTN2 | c.2504T>C p.F835S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63976395; called by muse, mutect2, varscan2
- ADAM28 | c.1921C>T p.H641Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs753877538, COSV56102167; called by muse, mutect2, varscan2
- ADAM29 | c.1554G>T p.E518D | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV63665284; called by muse, mutect2, varscan2
- ADAMTS10 | c.2317G>C p.G773R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99547537; called by muse, mutect2, varscan2
- ADAMTS20 | c.4819A>G p.S1607G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV67134384; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54455808; called by muse, mutect2, varscan2
- ADAMTSL5 | c.731G>T p.W244L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV57860902; called by muse, mutect2, varscan2
- ADCY1 | c.1945G>T p.V649L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99813121; called by muse, mutect2, varscan2
- ADCY2 | c.3158T>A p.L1053H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57882468; called by muse, mutect2, varscan2
- ADGRF4 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.169); catalogued as COSV51954062; called by muse, mutect2, varscan2
- ADGRL3 | c.3692C>A p.P1231H (on ENST00000506720 / NM_001322402.2; = p.P1163H on NM_015236.6) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV72231095; called by muse, mutect2, varscan2
- ADH1B | c.500T>A p.L167Q | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59297306; called by muse, mutect2
- AFF3 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV57859890; called by muse, mutect2, varscan2
- AGTPBP1 | c.2092A>G p.N698D (on ENST00000357081 / NM_001330701.2; = p.N658D on NM_015239.2) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV61273990; called by muse, mutect2, varscan2
- AHNAK2 | c.5879C>A p.A1960D | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV60920705; called by mutect2, varscan2
- ANK2 | c.57T>A p.S19R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.206); catalogued as COSV52171373; called by muse, mutect2, varscan2
- ANK2 | c.3245C>A p.P1082H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563830876, COSV52171385; called by muse, mutect2, varscan2
- ANKEF1 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs1352570511, COSV65692043; called by muse, mutect2, varscan2
- AOPEP | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV52920228; called by muse, mutect2, varscan2
- APLNR | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1048402746, COSV57243261; called by muse, mutect2, varscan2
- APOBR | c.2686G>A p.G896R (on ENST00000431282; = p.G905R on NM_018690.4) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as COSV60491818; called by muse, mutect2
- ASTN1 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV56074842; called by muse, mutect2, varscan2
- ASXL3 | c.1727C>A p.S576* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV52466640, COSV52471049; called by muse, mutect2, varscan2
- ATP10D | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV56709525; called by muse, mutect2, varscan2
- ATP8A2 | c.2378G>T p.C793F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54961848; called by muse, mutect2, varscan2
- AVPR1A | c.1078G>T p.V360F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV54547178; called by muse, mutect2, varscan2
- BCHE | c.1486G>A p.V496M | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1255083217, COSV52258882, COSV52258995; called by mutect2, varscan2
- BCOR | c.350A>T p.E117V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60711610; called by muse, mutect2, varscan2
- BEND2 | c.1640C>A p.A547E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV101192291; called by muse, mutect2, varscan2
- BMT2 | c.123G>C p.K41N | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV51778156; called by muse, mutect2
- BOD1L1 | c.7014G>T p.M2338I | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV50023428; called by muse, mutect2
- BOLL | c.217A>G p.K73E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56575343; called by muse, mutect2, varscan2
- BPNT1 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100435892; called by muse, mutect2
- C11orf16 | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV58167824; called by muse, mutect2, varscan2
- C1orf127 | c.1464G>T p.E488D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.979); catalogued as COSV65437846; called by muse, mutect2
- C2CD6 | c.578A>G p.N193S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.123); catalogued as COSV53797023; called by muse, mutect2
- CA6 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV66262453; called by muse, mutect2
- CACNA1A | c.1631G>T p.R544L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV100803454, COSV64216289; called by muse, mutect2, varscan2
- CACNA1A | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1349147232, COSV64194153; called by muse, mutect2, varscan2
- CACNA1S | c.3542C>T p.P1181L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs144935943; called by muse, mutect2
- CCDC136 | c.2872C>G p.Q958E | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV52801606; called by muse, mutect2
- CCP110 | c.3017G>T p.R1006L (on ENST00000381396 / NM_001323569.2; = p.A977= on NM_014711.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV51986178; called by muse, mutect2, varscan2
- CDC42BPA | c.1930A>G p.K644E | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV62014326; called by muse, mutect2, varscan2
- CDH10 | c.1043T>A p.V348D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52586796; called by muse, varscan2
- CDH6 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 5/62 reads (8%) | catalogued as COSV54073077, COSV99420176; called by muse, mutect2
- CDH9 | c.2102G>T p.R701M | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV50325132, COSV50451924; called by muse, mutect2, varscan2
- CDHR2 | c.3514A>T p.M1172L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99992296; called by muse, mutect2
- CFAP58 | c.870G>T p.Q290H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV57212769; called by muse, mutect2, varscan2
- CFAP74 | c.1672C>A p.L558I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54569919; called by muse, mutect2, varscan2
- CFAP74 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as rs746615855, COSV54569938; called by muse, mutect2, varscan2
- CFH | c.1916G>T p.G639V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66410340; called by muse, mutect2, varscan2
- CHRNA3 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104400326, COSV58776132; called by muse, mutect2, varscan2
- CHRNA4 | c.225C>A p.D75E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV64717834; called by muse, mutect2, varscan2
- CLCA2 | c.2165A>T p.Q722L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.444); catalogued as COSV65287825; called by muse, mutect2, varscan2
- CLDN16 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53228447; called by muse, mutect2, varscan2
- CLIP3 | c.1459G>T p.G487* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV53325165; called by muse, mutect2, varscan2
- CLSTN3 | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as COSV56938045; called by muse, mutect2, varscan2
- CLTCL1 | c.4571G>A p.S1524N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54233870; called by muse, mutect2, varscan2
- COL11A1 | c.4556G>T p.G1519V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62174945, COSV62188495; called by muse, mutect2, varscan2
- COL4A6 | c.3098G>T p.G1033V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57870853; called by muse, mutect2, varscan2
- COL6A5 | c.6620G>T p.G2207V (on ENST00000312481; = p.G2203V on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV55207459; called by muse, mutect2, varscan2
- CPA2 | c.283G>T p.V95L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV55980371; called by muse, mutect2, varscan2
- CPB1 | c.427A>T p.S143C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.722); catalogued as rs768717769, COSV51574680; called by muse, mutect2, varscan2
- CPE | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV68581250; called by muse, mutect2, varscan2
- CPXM2 | c.394G>C p.V132L | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV53865186; called by muse, mutect2, varscan2
- CROT | c.411G>T p.Q137H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV58975237; called by muse, mutect2
- CSMD1 | c.10306C>A p.L3436I (on ENST00000520002; = p.L3435I on NM_033225.6) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV59344424; called by muse, mutect2, varscan2
- CSMD1 | c.8147C>G p.T2716S (on ENST00000520002; = p.T2715S on NM_033225.6) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); catalogued as COSV59344441; called by muse, mutect2, varscan2
- CTNNA2 | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58161731; called by muse, mutect2, varscan2
- CYP11B2 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100011433, COSV59996680; called by muse, mutect2, varscan2
- DCC | c.985G>T p.V329F | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59113109; called by muse, mutect2, varscan2
- DIO3 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.869); catalogued as COSV63773993; called by muse, mutect2
- DLAT | c.1249A>G p.T417A | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV54771666; called by muse, mutect2, varscan2
- DMRT3 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV51903293, COSV51903429, COSV51906082; called by muse, mutect2, varscan2
- DMXL2 | c.971G>T p.R324M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51849845; called by muse, mutect2, varscan2
- DNAH12 | c.344G>T p.W115L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.335); catalogued as COSV60857568; called by muse, mutect2, varscan2
- DNAH9 | c.12292G>A p.A4098T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as rs201738395, COSV52358699; called by muse, mutect2, varscan2
- DSCAML1 | c.1490C>G p.P497R (on ENST00000321322; = p.P437R on NM_020693.4) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58395718; called by muse, mutect2, varscan2
- DSG4 | c.1675C>A p.P559T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV100355649, COSV57393661; called by muse, mutect2
- DUSP8 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV59030621; called by muse, mutect2
- DYSF | c.1903A>T p.T635S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV50463919; called by muse, mutect2, varscan2
- EEPD1 | c.1479G>T p.W493C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54197944, COSV54200181; called by muse, mutect2, varscan2
- EFCAB3 | c.56C>G p.P19R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59503052; called by muse, mutect2, varscan2
- ENDOD1 | c.1366G>C p.A456P | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53590066; called by muse, mutect2
- EP400 | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs546391201, COSV57777277; called by muse, mutect2, varscan2
- EPHA10 | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV60404358; called by muse, mutect2, varscan2
- ERICH3 | c.1566A>C p.Q522H | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58611076; called by muse, mutect2, varscan2
- EVI2B | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as COSV100445705; called by muse, mutect2, varscan2
- FAM209B | c.410T>A p.M137K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100991042; called by muse, mutect2, varscan2
- FAM209B | c.411G>T p.M137I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.235); catalogued as COSV100991043, COSV64915619; called by muse, mutect2, varscan2
- FAM47A | c.736C>A p.H246N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as COSV60498013; called by muse, mutect2, varscan2
- FANCM | c.2237C>T p.T746I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs773541028, COSV57503000; called by muse, mutect2, varscan2
- FAT4 | c.6938G>T p.S2313I | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV58694274; called by muse, mutect2, varscan2
- FCER1G | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV57155305; called by muse, mutect2, varscan2
- FCRL1 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV63826153; called by muse, mutect2, varscan2
- FGA | c.2145C>A p.H715Q | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57397724; called by muse, mutect2, varscan2
- FGD4 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.143); catalogued as COSV56786178; called by muse, mutect2
- FGD4 | c.1834A>C p.K612Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); catalogued as COSV56786186, COSV56787328; called by muse, mutect2, varscan2
- FIP1L1 | c.1466G>T p.R489L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60997822, COSV60998428; called by muse, varscan2
- FLG2 | c.3580C>A p.Q1194K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV66170171; called by muse, mutect2, varscan2
- FLT4 | c.531G>A p.W177* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV56113580; called by muse, mutect2, varscan2
- FN3KRP | c.716A>G p.Y239C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374117705, COSV53930224; called by mutect2, varscan2
- FRAS1 | c.1297G>C p.D433H | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV53624442, COSV53624523; called by muse, mutect2, varscan2
- FRAS1 | c.7843G>T p.A2615S | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as COSV53624479; called by muse, mutect2, varscan2
- FREM2 | c.3598G>A p.V1200M | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748241053, COSV54846044; called by muse, mutect2, varscan2
- FRY | c.7573G>T p.E2525* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV66573323; called by muse, mutect2, varscan2
- FURIN | c.690G>T p.E230D | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51575473; called by muse, mutect2, varscan2
- FUT3 | c.71T>C p.L24P | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57487163; called by muse, mutect2
- FYTTD1 | c.120G>C p.L40F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54084555; called by muse, mutect2, varscan2
- G2E3 | c.858G>T p.R286S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs770967781, COSV52841355; called by muse, mutect2, varscan2
- G3BP2 | c.479G>T p.R160I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV62976772; called by mutect2, varscan2
- GALNT17 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV61170763; called by muse, mutect2, varscan2
- GBA3 | c.896G>C p.G299A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.18); catalogued as rs894427092, COSV72438331; called by muse, mutect2
- GDPD2 | c.781G>T p.V261F | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV65533491; called by muse, mutect2, varscan2
- GJA5 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | catalogued as COSV54785056, COSV54787158; called by muse, mutect2, varscan2
- GLCCI1 | c.941A>G p.N314S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV56203123; called by muse, mutect2, varscan2
- GLP1R | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV64715657; called by muse, mutect2, varscan2
- GLRA2 | c.36G>T p.L12F | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV54343499; called by muse, mutect2, varscan2
- GPR65 | c.215A>T p.D72V | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV50863248; called by muse, mutect2, varscan2
- GRIP2 | c.790C>A p.H264N (on ENST00000619221; = p.H167N on NM_001080423.4) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV56122650; called by muse, varscan2
- HAT1 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV51363668; called by muse, mutect2, varscan2
- HBB | c.432C>A p.H144Q | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs36020563, COSV58942663; called by muse, mutect2, varscan2
- HCFC1 | c.3940C>T p.Q1314* | Nonsense Mutation (SNP) | VAF 38/199 reads (19%) | catalogued as COSV60074433; called by muse, mutect2, varscan2
- HDC | c.1454C>A p.P485H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV99984027, COSV99984379; called by muse, mutect2, varscan2
- HDC | c.1453C>A p.P485T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV99984380; called by muse, mutect2, varscan2
- HHIPL1 | c.431G>C p.R144T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV58091669; called by muse, mutect2, varscan2
- HS6ST3 | c.1028A>T p.N343I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.611); catalogued as COSV65012967; called by muse, mutect2
- HS6ST3 | c.1030A>T p.N344Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65012971; called by muse, mutect2
- IFITM2 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs371736596, COSV67714779; called by muse, mutect2, varscan2
- IFRD1 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as COSV50044540; called by muse, mutect2, varscan2
- IGSF22 | c.2579C>A p.T860K (on ENST00000319338; = p.T961K on NM_173588.4) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.307); catalogued as COSV55011120; called by muse, mutect2, varscan2
- IL7R | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100286768, COSV57412492; called by muse, mutect2, varscan2
- IL9R | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54900627; called by muse, mutect2, varscan2
- ILDR2 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.617); catalogued as rs1258075397, COSV54828593, COSV54835050; called by muse, mutect2, varscan2
- INPP5B | c.1336G>T p.A446S (on ENST00000373023; = p.A366S on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.86); catalogued as COSV65961592; called by muse, mutect2, varscan2
- ITGAX | c.1847G>T p.R616I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV51647796; called by muse, mutect2, varscan2
- KCNA5 | c.932C>A p.T311K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV52907136; called by muse, mutect2, varscan2
- KCNH5 | c.1325C>G p.T442R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59765579; called by muse, mutect2, varscan2
- KCNH5 | c.997C>A p.R333S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59765604; called by muse, mutect2, varscan2
- KCTD3 | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52068194; called by muse, mutect2
- KDR | c.842C>A p.S281Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV55769173; called by muse, mutect2, varscan2
- KIAA0232 | c.3429A>G p.I1143M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV56926802; called by muse, mutect2, varscan2
- KIF21A | c.4097-1G>T p.X1366_splice (on ENST00000361418 / NM_001378440.1; = p.X1353_splice on NM_017641.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/23 reads (35%) | catalogued as COSV62768265; called by muse, mutect2, varscan2
- KIF27 | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as COSV52829215; called by muse, mutect2, varscan2
- KIR2DL1 | c.818-2A>T p.X273_splice | Splice Site (SNP) | VAF 13/126 reads (10%) | catalogued as rs1390028106, COSV52412000; called by muse, mutect2, varscan2
- KIRREL2 | c.620G>T p.R207L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.142); catalogued as COSV52877753; called by muse, mutect2, varscan2
- KLHL1 | c.490G>C p.G164R | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV64775654; called by muse, mutect2, varscan2
- KLKB1 | c.1860G>T p.W620C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52995055, COSV52997191; called by muse, mutect2, varscan2
- KRT34 | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67450225; called by muse, mutect2, varscan2
- KRT38 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs748640709, COSV55845954, COSV55846677; called by muse, mutect2, varscan2
- KRT5 | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs267607456, CM087220, COSV52859824, COSV52861760; ClinVar: not provided; called by muse, mutect2, varscan2
- KRT6B | c.913-1G>A p.X305_splice | Splice Site (SNP) | VAF 17/109 reads (16%) | catalogued as COSV52884691; called by muse, mutect2, varscan2
- KTN1 | c.1765C>T p.H589Y | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs759587990, COSV68024215; called by muse, mutect2, varscan2
- LGR5 | c.1619A>T p.Q540L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV57006828; called by muse, mutect2, varscan2
- LRFN2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.322); catalogued as COSV57827803; called by muse, mutect2, varscan2
- LRP1B | c.13501G>T p.D4501Y | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV67243425; called by muse, mutect2, varscan2
- LRP1B | c.2596G>T p.G866C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63341836; called by muse, mutect2, varscan2
- LRRC34 | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57186774; called by muse, mutect2, varscan2
- LRRN3 | c.1889T>C p.M630T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs371192203; called by mutect2, varscan2
- MACIR | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV60635364; called by muse, mutect2, varscan2
- MAP2 | c.2798A>G p.K933R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV52297383; called by muse, mutect2
- MAP2K5 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV51618263; called by muse, mutect2, varscan2
- MAP3K15 | c.3410C>G p.A1137G | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV58833435; called by muse, mutect2, varscan2
- MAP3K19 | c.138+1G>T p.X46_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV59640381; called by muse, mutect2
- MED13 | c.4771G>T p.A1591S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67264960; called by muse, mutect2, varscan2
- MID2 | c.2107G>T p.G703C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53311420; called by muse, mutect2, varscan2
- MLF2 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV52571623; called by muse, mutect2, varscan2
- MOGAT1 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV104437594, COSV71479955; called by muse, mutect2, varscan2
- MPDZ | c.2594G>C p.S865T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs777657518, COSV59946465; called by muse, mutect2, varscan2
- MRGPRD | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.038); catalogued as COSV58422855, COSV58423503; called by muse, mutect2, varscan2
- MS4A5 | c.182C>A p.T61N | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55741472; called by muse, mutect2, varscan2
- MTARC1 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65055896; called by muse, mutect2, varscan2
- MUC16 | c.25679C>G p.S8560C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV67477061, COSV67487606; called by muse, mutect2, varscan2
- MUC16 | c.3235T>C p.S1079P | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV67477068; called by muse, mutect2
- MUC5B | c.10567C>A p.P3523T | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV71593778; called by mutect2, varscan2
- MUC5B | c.11216C>G p.A3739G | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.224); catalogued as COSV101500939; called by muse, mutect2, varscan2
- MUC5B | c.13520T>A p.L4507H | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.712); catalogued as COSV71593781; called by muse, mutect2, varscan2
- MXRA5 | c.8236C>G p.R2746G | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54240702, COSV54254614; called by muse, mutect2, varscan2
- MYH1 | c.5089G>T p.E1697* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV56851772; called by muse, mutect2, varscan2
- MYH7 | c.4744G>T p.E1582* | Nonsense Mutation (SNP) | VAF 33/151 reads (22%) | catalogued as COSV62520980; called by muse, mutect2, varscan2
- MYH7 | c.4172A>T p.K1391M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62520989; called by muse, mutect2
- MYO1C | c.638T>C p.V213A (on ENST00000648651 / NM_001080779.2; = p.V178A on NM_033375.5) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV100704606; called by muse, mutect2
- MYOM2 | c.2999-1G>T p.X1000_splice | Splice Site (SNP) | VAF 6/74 reads (8%) | catalogued as COSV50710345, COSV50730308; called by muse, mutect2
- NAV2 | c.3404C>A p.T1135K (on ENST00000396087 / NM_001244963.2; = p.T1112K on NM_145117.5) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.138); catalogued as COSV60661323; called by muse, mutect2, varscan2
- NAV3 | c.4378C>A p.P1460T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57092145; called by muse, mutect2, varscan2
- NCAN | c.3073G>C p.A1025P | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV53053769, COSV99386685; called by muse, mutect2, varscan2
- NEIL3 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV52811729; called by muse, mutect2, varscan2
- NES | c.3665G>T p.S1222I | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV63961616; called by muse, mutect2, varscan2
- NETO1 | c.470-1G>T p.X157_splice | Splice Site (SNP) | VAF 13/68 reads (19%) | catalogued as COSV100198452, COSV55001446; called by muse, mutect2, varscan2
- NEURL4 | c.3263G>T p.R1088I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV59751271; called by muse, mutect2, varscan2
- NID1 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV51623545; called by muse, mutect2, varscan2
- NLRP12 | c.1710G>T p.E570D | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV60750003; called by muse, mutect2, varscan2
- NLRP13 | c.2747G>T p.C916F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV61622703; called by muse, mutect2, varscan2
- NLRP14 | c.2483C>A p.T828K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55069008; called by muse, mutect2, varscan2
- NLRP7 | c.1776G>C p.K592N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as COSV60176928; called by muse, varscan2
- NLRP8 | c.3008del p.E1003Gfs*22 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as COSV52592299; called by mutect2, pindel*, varscan2
- NPTX2 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55717846; called by muse, mutect2, varscan2
- NPTX2 | c.1024C>A p.H342N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55717857; called by muse, mutect2, varscan2
- NRCAM | c.3131C>A p.A1044E (on ENST00000379028 / NM_001371124.1; = p.A1028E on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100694370, COSV61041331; called by muse, mutect2, varscan2
- NRXN3 | c.655C>A p.H219N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV73586037; called by muse, mutect2, varscan2
- OBSCN | c.3137A>G p.K1046R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.055); catalogued as COSV52791983; called by muse, mutect2, varscan2
- OCRL | c.2257del p.X753_splice | Splice Site (DEL) | VAF 11/48 reads (23%) | catalogued as COSV63982015; called by mutect2, pindel, varscan2
- OGDH | c.2099G>C p.C700S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.281); catalogued as COSV56052894; called by muse, mutect2, varscan2
- OGDHL | c.2392G>T p.A798S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV65103413; called by muse, varscan2
- OR10G8 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV70908798, COSV70908959; called by muse, mutect2, varscan2
- OR2A2 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs376133150; called by muse, mutect2, varscan2
- OR2H1 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1298440818, COSV65810970; called by muse, mutect2
- OR2L2 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63555910; called by muse, mutect2, varscan2
- OR2T12 | c.117C>A p.S39R | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV58777664; called by muse, mutect2, varscan2
- OR4C6 | c.326G>C p.G109A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.15); catalogued as COSV58604846; called by muse, mutect2, varscan2
- OR4Q3 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV59179282; called by muse, mutect2, varscan2
- OR51S1 | c.102G>T p.W34C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59059095; called by muse, mutect2, varscan2
- OR51T1 | c.392C>A p.P131Q | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59026463; called by muse, mutect2, varscan2
- OR5B21 | c.304T>A p.F102I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.693); catalogued as COSV64482072; called by muse, mutect2, varscan2
- OR5D18 | c.736C>A p.L246M | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV100450949; called by muse, mutect2, varscan2
- OR5D18 | c.737T>A p.L246Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100450950; called by muse, mutect2
- OR5K3 | c.252C>G p.N84K | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as COSV67350322; called by muse, mutect2, varscan2
- OR8H3 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 21/344 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV57909832, COSV57912321; called by muse, mutect2
- PACSIN1 | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs749648335, COSV55059553; called by muse, mutect2, varscan2
- PAX2 | c.443A>T p.H148L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV62291818; called by muse, mutect2, varscan2
- PAX2 | c.1028C>T p.P343L (on ENST00000428433 / NM_003987.5; = p.P320L on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747966683, COSV62291254; called by muse, mutect2, varscan2
- PCDH8 | c.1792C>A p.R598S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV100132076, COSV58813701; called by muse, mutect2, varscan2
- PCDHA1 | c.759G>C p.E253D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV65375236, COSV65377011; called by muse, mutect2, varscan2
- PCDHA3 | c.2128C>A p.L710M | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV63543291; called by muse, mutect2
- PCDHGA7 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV53978803; called by muse, mutect2, varscan2
- PCK1 | c.1759A>T p.K587* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV60129442; called by muse, mutect2, varscan2
- PCSK2 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV52734979, COSV52736809; called by muse, mutect2, varscan2
- PDHA2 | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV54780099; called by muse, mutect2, varscan2
- PEG3 | c.1349T>A p.M450K | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.921); catalogued as COSV55638546; called by muse, mutect2, varscan2
- PFKFB3 | c.1123A>C p.M375L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | PolyPhen benign (0.349); catalogued as COSV57990297; called by muse, mutect2
- PGK2 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.218); catalogued as COSV59163759, COSV59164487; called by muse, mutect2, varscan2
- PHF19 | c.821A>T p.Q274L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV56490127; called by muse, mutect2, varscan2
- PIEZO2 | c.7358C>A p.T2453K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53291282, COSV99555503; called by mutect2, varscan2
- PKHD1L1 | c.3442G>T p.E1148* | Nonsense Mutation (SNP) | VAF 48/155 reads (31%) | catalogued as COSV65746746; called by muse, mutect2, varscan2
- PLEC | c.10714G>C p.G3572R (on ENST00000322810 / NM_201380.4; = p.G3462R on NM_000445.5) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59656001; called by muse, mutect2, varscan2
- POLQ | c.3859A>T p.N1287Y | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV51755833; called by muse, mutect2, varscan2
- POLRMT | c.2935C>T p.Q979* | Nonsense Mutation (SNP) | VAF 11/123 reads (9%) | catalogued as COSV52116200; called by muse, mutect2
- POM121L12 | c.715A>T p.S239C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68693375; called by muse, mutect2, varscan2
- POSTN | c.1542C>G p.S514R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV65713567; called by muse, mutect2, varscan2
- PPIE | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV60971745; called by muse, mutect2, varscan2
- PPRC1 | c.3958C>T p.R1320* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV53386709; called by muse, mutect2, varscan2
- PROKR1 | c.553T>A p.L185M | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.41); catalogued as COSV100375815; called by muse, mutect2, varscan2
- PRR5 | c.706C>T p.R236C (on ENST00000336985 / NM_181333.4; = p.R227C on NM_015366.4) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); catalogued as rs756128125, COSV50060201; called by muse, mutect2, varscan2
- PRR5 | c.707G>T p.R236L (on ENST00000336985 / NM_181333.4; = p.R227L on NM_015366.4) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99135140; called by muse, mutect2, varscan2
- PRRG3 | c.519C>A p.S173R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.168); catalogued as COSV64851253; called by muse, mutect2, varscan2
- PRUNE2 | c.5830G>A p.A1944T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV65043479; called by muse, mutect2, varscan2
- PSME4 | c.2269G>A p.G757S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1224219787, COSV66366051; called by muse, mutect2, varscan2
- PTBP2 | c.632A>T p.K211M (on ENST00000426398 / NM_001300986.2; = p.K203M on NM_021190.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64625354; called by muse, mutect2, varscan2
- PTPRD | c.1462T>G p.Y488D | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61959735; called by muse, mutect2, varscan2
- PTPRN2 | c.1195C>G p.L399V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.221); catalogued as COSV67047258; called by muse, mutect2, varscan2
- PXDNL | c.3349C>A p.L1117I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.574); catalogued as COSV62492016, COSV62501091; called by muse, mutect2
- PXDNL | c.891G>T p.E297D | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.348); catalogued as COSV62492024, COSV62500367; called by muse, mutect2
- RALGAPA1 | c.5838G>T p.M1946I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV99356545; called by muse, mutect2, varscan2
- RAPGEF1 | c.18G>T p.Q6H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as COSV64700534; called by muse, mutect2
- RASSF6 | c.448C>G p.P150A (on ENST00000342081 / NM_201431.2; = p.P118A on NM_177532.5) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV56719433, COSV56721330; called by muse, mutect2, varscan2
- RDH12 | c.116G>C p.G39A | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as COSV99961960; called by muse, mutect2, varscan2
- RPAP2 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV72509432; called by mutect2, varscan2
- RPS27 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV55151305; called by muse, mutect2, varscan2
- RPS6KL1 | c.779T>C p.L260P | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV63581452; called by muse, mutect2, varscan2
- RTN1 | c.1627C>A p.L543M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV50731687; called by muse, mutect2, varscan2
- RUNX1T1 | c.1006C>A p.R336S (on ENST00000265814 / NM_001198628.1; = p.R309S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV56150330, COSV56152929; called by muse, mutect2, varscan2
- RUNX1T1 | c.384G>T p.R128S (on ENST00000265814 / NM_001198628.1; = p.R101S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56149591; called by muse, mutect2, varscan2
- RYR2 | c.14857C>A p.P4953T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63695514, COSV63704657; called by muse, mutect2, varscan2
- SBF2 | c.1395+1G>T p.X465_splice | Splice Site (SNP) | VAF 15/40 reads (38%) | catalogued as COSV56303394; called by muse, mutect2, varscan2
- SCML4 | c.574C>A p.L192M | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV64635745, COSV64636517; called by muse, mutect2
- SCN4A | c.5393C>A p.A1798E | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV71127619; called by muse, mutect2, varscan2
- SCNN1G | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.745); catalogued as COSV55597943, COSV55598317; called by muse, mutect2, varscan2
- SELENBP1 | c.779A>T p.D260V | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.13); catalogued as COSV64373713; called by muse, mutect2, varscan2
- SENP5 | c.276G>T p.L92F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV60208434; called by muse, mutect2, varscan2
- SERPINI1 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV55509404, COSV55512238; called by muse, mutect2, varscan2
- SF3B2 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV59428937; called by muse, mutect2, varscan2
- SHOX2 | c.779C>A p.A260E (on ENST00000441443 / NM_006884.3; = p.A284E on NM_003030.4) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs145675724; called by muse, mutect2, varscan2
- SIGLEC6 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.11); catalogued as COSV58433617, COSV58435481; called by muse, mutect2, varscan2
- SIGLEC9 | c.741C>A p.D247E | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV51582435, COSV51585838; called by muse, mutect2, varscan2
- SLC25A51 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV54253201; called by muse, mutect2
- SLC32A1 | c.1427T>C p.F476S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54147362; called by muse, mutect2
- SLC4A10 | c.1052G>T p.R351M (on ENST00000446997 / NM_001354461.2; = p.R321M on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55786221; called by muse, mutect2, varscan2
- SNTG1 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); catalogued as COSV52454596; called by muse, mutect2
- SORL1 | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV52757244; called by muse, mutect2
- SP3 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59469122; called by mutect2, varscan2
- SPAM1 | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201663309; called by muse, mutect2, varscan2
- SPATA18 | c.818G>C p.R273T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.249); catalogued as COSV54646840; called by muse, mutect2, varscan2
- SPEF2 | c.3018G>T p.K1006N | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV61550117; called by muse, mutect2, varscan2
- SRGAP1 | c.904A>T p.I302F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV61900070; called by muse, mutect2, varscan2
- SRGAP3 | c.673-2A>T p.X225_splice | Splice Site (SNP) | VAF 11/59 reads (19%) | catalogued as COSV64535675; called by muse, mutect2, varscan2
- STYXL2 | c.499G>C p.A167P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54806358, COSV54807008; called by muse, mutect2, varscan2
- STYXL2 | c.1556A>T p.D519V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54807016; called by muse, mutect2, varscan2
- SUGT1 | c.958G>T p.G320C (on ENST00000343788 / NM_001130912.3; = p.G288C on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59422634; called by muse, varscan2
- SUSD5 | c.365C>A p.P122Q | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58878869; called by muse, mutect2, varscan2
- SVEP1 | c.8082C>A p.N2694K | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as COSV52835151, COSV52840938; called by muse, mutect2
- SVIL | c.210A>T p.Q70H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV63445076; called by muse, mutect2, varscan2
- SYCE1 | c.853C>A p.H285N (on ENST00000343131 / NM_001143764.3; = p.H249N on NM_130784.3) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as COSV58218152; called by muse, mutect2, varscan2
- SYNE3 | c.2728-2A>G p.X910_splice | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100516677; called by muse, mutect2, varscan2
- TCHHL1 | c.2559C>A p.S853R | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as COSV64286419; called by muse, mutect2, varscan2
- TENM4 | c.8054A>T p.E2685V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53643155; called by muse, mutect2
- THBS2 | c.233T>C p.M78T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV64680140; called by muse, mutect2, varscan2
- TP53 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52689817, COSV52759537, COSV52925149; called by muse, mutect2, varscan2
- TP63 | c.455C>A p.P152H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV53211252; called by muse, mutect2, varscan2
- TPX2 | c.1677G>T p.Q559H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV55920632, COSV99038840; called by muse, mutect2, varscan2
- TRHDE | c.2744T>G p.L915R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.977); catalogued as COSV53852111; called by muse, mutect2, varscan2
- TRMT2A | c.130A>G p.K44E | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV52814132; called by muse, mutect2, varscan2
- TRPM3 | c.2584C>A p.L862I (on ENST00000357533 / NM_001366142.2; = p.L705I on NM_020952.6) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62589261; called by muse, mutect2, varscan2
- TSHZ2 | c.2429C>A p.P810Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV61589732; called by muse, mutect2
- TTN | c.51451A>C p.I17151L (on ENST00000591111; = p.I9727L on NM_003319.4) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | PolyPhen benign (0.051); catalogued as COSV60168188; called by muse, mutect2, varscan2
- TUBB4A | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.292); catalogued as COSV51158320; called by muse, mutect2, varscan2
- UBE2S | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52740940; called by muse, mutect2
- UGT2A3 | c.1430C>G p.A477G | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52360647, COSV52360935; called by muse, mutect2, varscan2
- UGT3A2 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56931663; called by muse, mutect2, varscan2
- UMOD | c.1352G>T p.G451V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV56777110; called by muse, mutect2, varscan2
- USP1 | c.1813A>T p.S605C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV52012173; called by muse, mutect2, varscan2
- USP18 | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV53173886; called by muse, mutect2, varscan2
- USP33 | c.2224A>G p.I742V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV62470202; called by muse, mutect2, varscan2
- VAT1L | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV56822921; called by muse, mutect2
- VIT | c.1768A>T p.K590* (on ENST00000389975 / NM_001177969.1; = p.K605* on NM_053276.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV64897607; called by muse, mutect2, varscan2
- VPS13C | c.2584G>T p.G862C (on ENST00000644861 / NM_020821.3; = p.G819C on NM_017684.5) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV51287965; called by muse, mutect2, varscan2
- VWA3B | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1167914535, COSV68244299; called by muse, mutect2
- WAPL | c.3372C>A p.Y1124* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV53937325; called by muse, mutect2, varscan2
- WNT7A | c.204G>T p.M68I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV53200274; called by muse, mutect2, varscan2
- XKR6 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58657472; called by muse, mutect2, varscan2
- YBX3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV54386137; called by muse, mutect2, varscan2
- ZAN | c.1470C>A p.Y490* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV61811196; called by muse, mutect2
- ZCCHC14 | c.2716C>G p.L906V (on ENST00000268616; = p.L1043V on NM_015144.3) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.306); catalogued as rs1447438273, COSV51887801; called by muse, mutect2, varscan2
- ZEB2 | c.865A>T p.K289* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as COSV57960313; called by muse, mutect2, varscan2
- ZIC4 | c.27G>T p.M9I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV67172659; called by muse, mutect2, varscan2
- ZKSCAN3 | c.372G>T p.L124F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52853144; called by muse, mutect2, varscan2
- ZNF117 | c.1393A>T p.I465L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.076); catalogued as COSV51428557; called by muse, mutect2
- ZNF200 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.142); catalogued as rs1202854102, COSV67724057; called by muse, mutect2, varscan2
- ZNF260 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV72951250; called by muse, mutect2, varscan2
- ZNF536 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62827708; called by muse, mutect2, varscan2
- ZNF585A | c.305G>T p.W102L (on ENST00000292841 / NM_001288800.2; = p.W47L on NM_152655.3) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV53063036, COSV53065067; called by muse, mutect2, varscan2
- ZNF804B | c.3885G>T p.L1295F | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.24); catalogued as COSV60836544; called by muse, mutect2
- ZNF99 | c.2269G>A p.A757T | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV68055237; called by muse, mutect2
- ADAMTSL3 | c.4222dup p.T1408Nfs*4 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- AHNAK2 | c.10573_10574insA p.P3525Hfs*5 | Frame Shift Ins (INS) | VAF 36/190 reads (19%) | called by mutect2, varscan2
- DEFB116 | c.188dup p.N63Kfs*2 | Frame Shift Ins (INS) | VAF 30/250 reads (12%) | called by mutect2, pindel, varscan2
- KIR2DS4 | c.678C>A p.N226K | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- LGR6 | c.2661del p.P889Lfs*11 (on ENST00000367278 / NM_001017403.1; = p.P837Lfs*11 on NM_021636.3) | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- MFNG | c.137dup p.P48Afs*3 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- MRC1 | c.3250+1G>T p.X1084_splice | Splice Site (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- OR2T29 | c.254T>G p.M85R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PCNT | c.6097del p.E2033Sfs*5 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel, varscan2
- SH3BGR | c.167del p.G56Efs*22 | Frame Shift Del (DEL) | VAF 36/147 reads (24%) | called by mutect2, pindel, varscan2
- SH3RF1 | c.1342_1343del p.S448Cfs*15 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- STRN4 | c.1051del p.V351Sfs*20 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
- TRAV5 | c.27C>G p.F9L | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TRBV27 | c.11A>T p.Q4L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRBV3-1 | c.233C>A p.T78K | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- UROC1 | c.1387del p.V463Sfs*18 | Frame Shift Del (DEL) | VAF 31/170 reads (18%) | called by mutect2, varscan2
- VCAN | c.8064dup p.T2689Hfs*10 | Frame Shift Ins (INS) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- VCX2 | c.203A>C p.E68A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.024); called by muse, mutect2
- ZNF229 | c.1539del p.Q514Sfs*306 | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | called by mutect2, varscan2
- A2ML1 | c.2253G>A p.A751= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs375611706; ClinVar: likely benign; called by muse, mutect2, varscan2
- ABCG8 | c.1251C>A p.L417= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as COSV55394553, COSV55396725; called by muse, mutect2
- ABRACL | c.120C>T p.A40= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV62771592; called by muse, mutect2, varscan2
- ACACA | c.1047C>T p.A349= | Silent (SNP) | VAF 34/174 reads (20%) | called by muse, mutect2, varscan2
- ACSS3 | c.267C>T p.P89= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV54094932; called by muse, mutect2, varscan2
- ADCY1 | c.1944G>T p.L648= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV99813118; called by muse, mutect2, varscan2
- ADGRF2 | c.1290C>A p.T430= (on ENST00000296862 / NM_001368115.2; = p.T362= on NM_153839.7) | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs754447273, COSV57289567, COSV57291294; called by muse, mutect2, varscan2
- AIRE | c.453C>T p.T151= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs554372593, COSV52395151; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKRD12 | c.966A>T p.V322= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV50832590; called by muse, mutect2, varscan2
- APAF1 | c.2829A>T p.I943= (on ENST00000551964 / NM_181861.2; = p.I889= on NM_001160.3) | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV59665567; called by mutect2, varscan2
- ASB11 | c.240C>A p.A80= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV60355700; called by muse, mutect2, varscan2
- ASXL3 | c.5100T>A p.S1700= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV52471066; called by muse, mutect2, varscan2
- CACNA1E | c.999C>T p.P333= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs758021122, COSV100702615, COSV62403393; called by muse, mutect2, varscan2
- CALCR | c.1011G>T p.R337= (on ENST00000649521 / NM_001164737.2; = p.R321= on NM_001742.4) | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV64009601; called by muse, mutect2, varscan2
- CAMSAP2 | c.2253G>T p.R751= (on ENST00000236925 / NM_001297707.2; = p.R740= on NM_203459.3) | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV52673253; called by muse, mutect2, varscan2
- CAPS | c.378C>G p.A126= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV50383180; called by muse, mutect2, varscan2
- CDHR2 | c.3513C>A p.T1171= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99992295; called by muse, mutect2
- CDK17 | c.303A>G p.L101= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1301600290, COSV54131026; called by muse, mutect2
- CHRNA6 | c.327C>T p.R109= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs1186664338, COSV52380175; called by muse, mutect2, varscan2
- CLEC14A | c.846C>T p.D282= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV60563233; called by muse, mutect2
- CLEC4D | c.141A>C p.S47= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV55229571; called by muse, mutect2, varscan2
- COG4 | c.1026G>T p.L342= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV60423687; called by muse, mutect2, varscan2
- COL19A1 | c.3075G>A p.E1025= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1259672274, COSV59569696, COSV59577850; called by muse, mutect2, varscan2
- DCBLD1 | c.1407G>T p.L469= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV51643130; called by muse, mutect2, varscan2
- DCDC1 | c.4899C>T p.H1633= (on ENST00000597505 / NM_001367979.1; = p.H740= on NM_020869.3) | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs773940703, COSV58000518; called by muse, mutect2, varscan2
- DIO1 | c.129C>A p.A43= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV50778022; called by muse, mutect2, varscan2
- ECHDC1 | c.609C>A p.I203= (on ENST00000531967 / NM_001139510.1; = p.I197= on NM_001002030.2) | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV58933084; called by muse, mutect2, varscan2
- EPHB2 | c.631C>T p.L211= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV65863714; called by muse, mutect2
- ERBB4 | c.1794G>A p.Q598= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV53550126; called by muse, mutect2, varscan2
- EVI2B | c.459C>A p.V153= | Silent (SNP) | VAF 23/149 reads (15%) | catalogued as COSV100445710; called by muse, mutect2, varscan2
- FAR2 | c.658A>C p.R220= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV51727117; called by muse, varscan2
- FEM1B | c.681C>A p.A227= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV60988937; called by muse, mutect2, varscan2
- GABRQ | c.1335C>A p.A445= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV64782731; called by muse, mutect2, varscan2
- GFAP | c.393C>G p.T131= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV53651685; called by mutect2, varscan2
- GLI3 | c.1191T>G p.P397= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV67890733, COSV67892464; called by muse, mutect2, varscan2
- GLUD2 | c.1233A>G p.P411= | Silent (SNP) | VAF 29/188 reads (15%) | catalogued as COSV60152335; called by muse, mutect2, varscan2
- GRIN3A | c.1533T>C p.S511= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV62455698; called by muse, mutect2, varscan2
- IL16 | c.1290C>A p.P430= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV57265548; called by muse, mutect2, varscan2
- ITLN1 | c.645C>T p.D215= | Silent (SNP) | VAF 13/153 reads (8%) | catalogued as rs142057123; called by muse, mutect2
- KCNK10 | c.1578G>T p.R526= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV56647693; called by muse, mutect2, varscan2
- KCNN2 | c.36G>A p.R12= (on ENST00000264773; = p.R224= on NM_021614.4) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs759360717, COSV53290766, COSV53292895; called by muse, mutect2
- KRT10 | c.123C>A p.G41= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV54090409; called by muse, varscan2
- KRT13 | c.339C>T p.D113= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV55840478; called by muse, mutect2, varscan2
- LILRA1 | c.57C>A p.T19= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV52182248; called by muse, mutect2, varscan2
- LMX1B | c.459C>T p.G153= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs779330478, COSV62739376; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP1B | c.4422T>A p.A1474= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV67243430; called by muse, mutect2
- MDH1B | c.816C>T p.A272= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs1397821477, COSV65590382; called by muse, mutect2, varscan2
- MED12L | c.816C>A p.L272= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV56385341; called by muse, mutect2, varscan2
- MRC2 | c.1425G>C p.R475= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV57641560; called by muse, mutect2, varscan2
- MYH11 | c.3636T>A p.L1212= | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as COSV55548239, COSV55559017; called by muse, mutect2, varscan2
- MYO1C | c.639G>T p.V213= (on ENST00000648651 / NM_001080779.2; = p.V178= on NM_033375.5) | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs1567529559, COSV100704605; called by muse, mutect2
- MYOD1 | c.168C>T p.L56= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV51454321; called by muse, mutect2
- NLRP7 | c.1761G>T p.V587= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs1475546179, COSV60176940; called by muse, varscan2
- NPHP3 | c.348G>A p.E116= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV58128787; called by muse, mutect2, varscan2
- NTRK2 | c.120C>A p.A40= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV52869986; called by muse, mutect2, varscan2
- OR10A2 | c.612C>G p.S204= | Silent (SNP) | VAF 25/194 reads (13%) | catalogued as COSV56299868; called by muse, mutect2, varscan2
- OR10C1 | c.525C>A p.I175= (on ENST00000622521; = p.I173= on NM_013941.3) | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as COSV65823392; called by muse, mutect2, varscan2
- OR56A3 | c.771C>A p.T257= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as COSV100290386, COSV61569525; called by muse, varscan2
- OR6K3 | c.513C>T p.I171= (on ENST00000368146; = p.I155= on NM_001005327.2) | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV63745957; called by muse, mutect2, varscan2
- OTOP1 | c.816C>A p.P272= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV56394531, COSV56394545; called by muse, mutect2, varscan2
- PAK1 | c.789G>T p.V263= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV53698122, COSV53698174; called by muse, mutect2, varscan2
- PAPPA2 | c.4527T>A p.L1509= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV62802441; called by muse, mutect2, varscan2
- PAX4 | c.1038A>T p.L346= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV58389690; called by muse, mutect2
- PCDHA4 | c.36G>T p.R12= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV100793125, COSV100793849; called by muse, mutect2, varscan2
- PCDHGA3 | c.274C>A p.R92= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs1372591495, COSV53978786, COSV99550080; called by muse, mutect2, varscan2
- PCLO | c.8430A>C p.T2810= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV61646509; called by muse, mutect2, varscan2
- PHF12 | c.624G>A p.R208= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV52020466; called by muse, mutect2, varscan2
- PILRA | c.885G>A p.E295= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV52201123; called by muse, mutect2, varscan2
- PPEF1 | c.1080G>T p.L360= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV62996083; called by muse, mutect2, varscan2
- RBBP7 | c.1020C>A p.R340= | Silent (SNP) | VAF 54/187 reads (29%) | catalogued as COSV58113183; called by muse, mutect2, varscan2
- RDH12 | c.117C>A p.G39= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV99961962; called by muse, mutect2, varscan2
- RGR | c.21G>T p.L7= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV63894594; called by muse, mutect2, varscan2
- RNF157 | c.756T>C p.Y252= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs774430994, COSV53946006; called by muse, mutect2, varscan2
- RP1 | c.3906C>G p.V1302= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV55120377, COSV55124209; called by muse, mutect2, varscan2
- RYR1 | c.6282G>A p.L2094= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV62095358, COSV62102237; called by muse, mutect2, varscan2
- RYR2 | c.5481C>A p.T1827= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV63695500; called by muse, mutect2, varscan2
- SCN1A | c.3387G>A p.T1129= (on ENST00000303395 / NM_001202435.3; = p.T1118= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs375953445; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SERPINA6 | c.57C>G p.T19= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV104419917, COSV58585988; called by muse, mutect2, varscan2
- SIGLEC1 | c.1356G>T p.L452= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV52466886; called by muse, mutect2, varscan2
- SIGLEC9 | c.72G>A p.T24= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs373690399; called by muse, mutect2, varscan2
- SLC26A3 | c.1059G>T p.V353= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV60641154; called by muse, mutect2, varscan2
- SLC4A4 | c.1167T>A p.I389= (on ENST00000264485 / NM_001098484.3; = p.I345= on NM_003759.4) | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV52629062; called by muse, mutect2, varscan2
- STC2 | c.588G>A p.Q196= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs762071344, COSV54179493; called by muse, mutect2, varscan2
- TEKT4 | c.102C>T p.F34= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV54626179; called by muse, mutect2, varscan2
- TMEM119 | c.315C>A p.A105= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV67188930; called by muse, mutect2
- TMPRSS15 | c.1848C>A p.L616= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV53042792; called by muse, mutect2, varscan2
- TRIOBP | c.5463T>C p.Y1821= (on ENST00000644935 / NM_001039141.3; = p.Y108= on NM_007032.5) | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV58526010; called by muse, mutect2
- TRPM2 | c.2346C>A p.G782= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV55972262, COSV55975942; called by muse, mutect2
- TSHZ1 | c.3090G>A p.E1030= (on ENST00000580243 / NM_001308210.2; = p.E985= on NM_005786.6) | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs1473328098, COSV59012636; called by muse, varscan2
- TSHZ2 | c.1011A>T p.T337= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV61587137; called by muse, mutect2, varscan2
- UGGT2 | c.1014C>T p.N338= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV65025565; called by muse, mutect2, varscan2
- UGT1A5 | c.474G>T p.A158= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as rs147117995, COSV59392455; called by muse, mutect2, varscan2
- UNC5C | c.2544C>A p.I848= | Silent (SNP) | VAF 40/148 reads (27%) | catalogued as COSV71660912; called by muse, mutect2, varscan2
- USH2A | c.2529C>A p.L843= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as COSV56393521, COSV56435477; called by muse, mutect2, varscan2
- WDR91 | c.1083A>T p.P361= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV60370804; called by muse, mutect2, varscan2
- WEE2 | c.678C>A p.V226= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV66879457; called by muse, mutect2, varscan2
- WSCD2 | c.216G>T p.L72= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV54585739; called by muse, varscan2
- YES1 | c.942A>G p.P314= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs773565802, COSV100100037; called by muse, mutect2, varscan2
- ZNF202 | c.1575A>T p.T525= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV60247611; called by muse, mutect2, varscan2
- ZNF324B | c.72C>T p.A24= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV60742424; called by muse, mutect2, varscan2
- ZNF536 | c.3795G>T p.L1265= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1013587961, COSV62827713; called by muse, mutect2, varscan2
- AL109984.1 | chr20:52097394 G>A | 3'Flank (SNP) | VAF 45/225 reads (20%) | catalogued as rs1477365817, COSV63750505; called by muse, mutect2, varscan2
- ANKRD20A5P | n.434G>A | RNA (SNP) | VAF 24/139 reads (17%) | catalogued as rs4101176; called by muse, mutect2, varscan2
- ARMC5 | c.1864+151A>T | Intron (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99192913; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1501C>A | 3'UTR (SNP) | VAF 16/114 reads (14%) | catalogued as COSV57543496; called by muse, mutect2, varscan2
- DLC1 | c.1348+90511G>C | Intron (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99366210; called by muse, mutect2, varscan2
- FAM166C | c.*1G>T | 3'UTR (SNP) | VAF 13/51 reads (25%) | catalogued as COSV56599091; called by muse, mutect2, varscan2
- HUWE1 | c.1490-684A>C | Intron (SNP) | VAF 6/33 reads (18%) | called by mutect2, varscan2
- IGHG1 | chr14:105737789 G>A | 3'Flank (SNP) | VAF 6/34 reads (18%) | catalogued as rs768707951; called by muse, varscan2
- LRRC71 | c.1563+91C>A | Intron (SNP) | VAF 20/84 reads (24%) | catalogued as COSV100168256, COSV100169077; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85597C>A | Intron (SNP) | VAF 16/73 reads (22%) | catalogued as COSV72279631; called by muse, mutect2, varscan2
- OR2W5 | n.1230G>C | RNA (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- PCDHA9 | c.2394+62T>G | Intron (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100970208; called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559171 G>T | 5'Flank (SNP) | VAF 19/57 reads (33%) | catalogued as rs751498529; called by muse, mutect2, varscan2
- TRPM1 | c.724+980C>A | Intron (SNP) | VAF 21/91 reads (23%) | catalogued as COSV56637335; called by muse, mutect2, varscan2
